Somatic mutation profile of tumor specimen MP2PRT-PATISM-TMP1-A (aliquot MP2PRT-PATISM-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATISM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (912 days).
Specimen MP2PRT-PATISM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dd4176f-72b6-4ada-a11e-2e4c4ec9d38f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATISM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATISM-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e663d5b-ae2f-417f-8001-a71f613a4086

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRM7 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 113/317 reads (36%) | catalogued as rs1312633998, COSV100735140, COSV63130661; called by muse, mutect2, varscan2
- IKZF3 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 279/401 reads (70%) | catalogued as COSV53101693; called by muse, mutect2, varscan2
- IKZF3 | c.1529G>T p.*510Lext*19 | Nonstop Mutation (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
